Surgical pathology report (de-identified scan), TCGA case TCGA-14-0813, project TCGA-GBM (Glioblastoma Multiforme), tissue source site Emory University, specimen TCGA-14-0813-01A (Primary Tumor).

[page 1 of 4]
AP Report

* Final Report *

14-0813

Document Type: AP Report
Document Date: [REDACTED]
Document Status: Auth (Verified)
Document Title: Anatomic Pathology Report
Encounter info: [REDACTED]

* Final Report *

Anatomic Pathology Report

Patient: [REDACTED] Accession Number: [REDACTED]
Patient Number: [REDACTED] Date Collected: [REDACTED]
Financial Number: [REDACTED] Date Received: [REDACTED]
Room/Bed: [REDACTED] PT: [REDACTED]
Admitting Physician: [REDACTED]
Ordering Physician: [REDACTED]

SURGICAL PATHOLOGY REPORT

DIAGNOSIS:

1. LEFT TEMPORAL LESION, RESECTION, FS1A, TP1A:
- GLIOBLASTOMA (WHO GRADE IV).
- SEE COMMENT.
2. LEFT TEMPORAL LESION, RESECTION:
- GLIOBLASTOMA (WHO GRADE IV).
- SEE COMMENT.

COMMENT:

This tumor shows multiple morphologies. Some regions show epithelioid and solid growth patterns while others are more classically fibrillar. Immunohistochemistry for GFAP shows that tumor cells are strongly positive.

SPECIMEN:

1. Left temporal lesion.
2. Left temporal lesion.

CLINICAL HISTORY/OPERATIVE FINDINGS:

Printed by: [REDACTED]
Printed on: [REDACTED]

Page 1 of 4
(Continued)

[page 2 of 4]
AP Report

* Final Report *

Brain tumor.

14-0813

PREVIOUS OPERATION OR BIOPSY: Not provided.

NAME OF OPERATION: Left temporal craniotomy.

PREOPERATIVE AND/OR POSTOPERATIVE DIAGNOSIS: Not provided.

GROSS DESCRIPTION:

Received are two specimens, both are labeled with the patient's name and medical record number.

Specimen #1 is received fresh for intraoperative consultation and consists of multiple fragments of tan, soft tissue measuring in aggregate 1.0 x 1.0 x 0.3 cm. A portion of the specimen is frozen for intraoperative consultation and resubmitted for permanent in cassette "FS1A". The remainder of the specimen is submitted in cassette "1B".

Specimen #2 is received in formalin and consists of multiple fragments of tan and white, hemorrhagic, soft tissue measuring in aggregate 2.0 x 1.0 x 0.4 cm. The specimen is submitted in its entirety in cassette "2A".

INTRAOPERATIVE CONSULTATION:

FS1A: LEFT TEMPORAL LESION (FROZEN SECTION): MALIGNANT NEOPLASM; FAVOR GLIOBLASTOMA.

MICROSCOPIC DESCRIPTION:

Microscopic examination performed.

TISSUE COMMITTEE CODE:

1

Resident: _

Page 1 (Continued...)

Printed by:
Printed on:

Page 2 of 4
(Continued)

[page 3 of 4]
AP Report

* Final Report *

Patient: [REDACTED]
Patient Number: [REDACTED]

Accession Number: [REDACTED]

14-0813

SURGICAL PATHOLOGY REPORT

Fellow: _

The pathologist has reviewed and interpreted the case with the resident/fellow.

SPECIAL STAINS:

AE1/AE3	DONE
GFAP	DONE
S-100	DONE

Printed by:
Printed on:

Page 3 of 4
(Continued)

[page 4 of 4]
AP Report

[REDACTED], [REDACTED] - [REDACTED]

* Final Report *

14-0813

Medical Records

Page 2 (End of Report)

Printed by:
Printed on:

Page 4 of 4
(End of Report)

Source: NCI Genomic Data Commons file a1284c6d-107c-4e51-8caa-2f0afd7fc0b2 (TCGA-14-0813.B0AC7F13-95E5-4B55-9DE6-2EFB7D0A2D91.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).